Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KD, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KD-01A (Primary Tumor).

[page 1 of 4]
printed:

UUID: 20DFC61D-E721-4798-A88C-808785CE740A TCGA-VD-A8KD-01A-PR Redacted		Page 1 of 4
		REPORT Tel:
Forename: 	Sex: 	Clinical Consultant & Location
Unit No: 		

This Copy For:

SPECIMEN

Left globe

CLINICAL DETAILS

Left choroidal melanoma and blind eye with increased intraocular pressure.

MACROSCOPIC DESCRIPTION

An intact left eye.

Dimensions: Axial 25.5mm, Horizontal 23.7mm, Vertical 23.5mm

Cornea: Horizontal 13mm, Vertical 11mm

Optic nerve
Length 7mm, Diameter 3.5mm

Pupil: dislocated supratemporally.

On trans-illumination, superior half is filled with shadow approx 22 x 15mm.

Plane of section: vertical

Intraocular description:

Sectioning reveals a large mushroom shaped tumour which is partly pigmented and partly pale/amelanotic. Tumour projects into vitreous cavity posteriorly to obscure the optic disc and anteriorly up to the back of the lens.

Tumour size

LBD 18.3mm, Height 17.4mm

MICROSCOPY

Sections show a partly pigmented choroidal melanoma composed of mixed cells in which the epithelioid component amounts to approximately 25% and appears to correspond to most of the amelanotic component described macroscopically. Tumour cells express Melan-A and HSP 27 (score 2). The number of mitosis

ICD O-3
Melanoma, epithelioid & spindle cell
mixed 8770/3
Date: 11/17/14
Choroid C69.3

Reported:

Pathologist:

Electronically Verified:

[page 2 of 4]
Department of Pathology

Page 2 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

is approximately 7/40 high power fields. The microvasculature of the melanoma is prominent, and closed loops are present in the planes of section. The lymphocytic infiltrate within the tumour is moderate, and scattered macrophages are also present. Tumour necrosis is not seen. There is no tumour extension through the optic nerve or its resection margin. There is, however, tumour extending into the sclera. In addition, sections of vortex veins reveal focal tumour infiltration in at least one vessel.

Elsewhere, the cornea shows oedema of basal epithelial cells. The anterior chamber angles are focally closed and the anterior chamber is filled with proteinaceous fluid. The ciliary body appears atrophic with hyalinisation of ciliary processes. Focal pigmented iris epithelium is adherent to the anterior surface of the lens. There is extensive retinal detachment. Bruch's membrane adjacent to the tumour is disrupted in the sections examined. Vitreous is haemorrhagic.

DIAGNOSIS

Left enucleation - Choroidal melanoma of mixed cell type with infiltration into sclera and vortex vein.

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	2= Closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	Yes
MITOTIC FREQUENCY	7/40 HPF
DIFFUSE MELANOMA	No

Reported:

Pathologist:

Electronically Verified:

[page 3 of 4]
HISTOPATHOLOGY REPORT Tel:

Surname	Lab No		Clinical Consultant & Location
Forename(s)	DOB/Age	Sex	
Unit No	Request Date		

This Copy For:

SPREAD 3= Trans-scleral
5= Vortex Vein

CLEARANCE 3= Uncertain

HSP-27 POSITIVITY 2= 21-70%

LARGE DIAMETER	18.3 mm
THICKNESS	17.4 mm

COMMENTS :

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8.

A supplementary report will follow in due course.

MOLECULAR ANALYSIS

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue (from both melanotic and amelanotic areas) was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

Reported:

Pathologist:

Electronically Verified:

[page 4 of 4]
Department of Pathology

Page 4 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

Normal (disomy) chromosome 1, monosomy 3, normal chromosome 6 and gains (polysomy) in chromosome 8.

Taken together with the histomorphological features of the tumour, these molecular data would place the patient in the high risk group with respect to the development of metastatic melanoma.

Consideration of clinical features of the tumour is, however, also required.

Reported:

Pathologist:

Electronically Verified:

Criteria	11/16/13	Yes	No

Source: NCI Genomic Data Commons file ce77ef3a-70a0-4ed3-aee9-b07ccea4c0bf (TCGA-VD-A8KD.20DFC61D-E721-4798-A88C-808785CE740A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).